Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1D9, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1D9-01A (Primary Tumor).

1CD-0-3
Adenocarcinoma, NOS 8140/3
Site Code: Cecum C18.0

1/10/11
pw

(First Tumor)

Tumor Site:	Cecum Proximal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	None
Crohn's like reaction	☒ None ☐ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	1.8
Pathologist Comment:	

Source: NCI Genomic Data Commons file fcdb4020-7ee9-4100-acbb-920bd87b2074 (TCGA-DM-A1D9.879D9864-FDFE-4D40-A90A-2D8694148298.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).